CCDI case PBCBYB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/fa6f41ff-341b-4ffd-b713-d3e235eff316

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyoma, NOS: ICD-O-3 morphology code: 8900/0; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 16.8 years (6,123 days).

Biospecimens (3 samples)
- Sample 0DODM7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DODMZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DODNZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
